Somatic mutation profile of tumor specimen TCGA-12-0821-01A (aliquot TCGA-12-0821-01A-01D-1492-08) from TCGA case TCGA-12-0821, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 62.8 years (22,949 days).
Specimen TCGA-12-0821-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5478ba68-d772-4e3f-95fd-4021b6ce8547.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-0821-10A (Blood Derived Normal), aliquot TCGA-12-0821-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c504b477-f051-43ed-bb74-5cd185caefb3

The open-access MAF lists 60 somatic variants for this specimen: 41 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 18, Nonsense Mutation 6, Splice Site 2, Translation Start Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AK5 | c.1579C>T p.P527S (on ENST00000354567 / NM_174858.3; = p.P501S on NM_012093.4) | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.99); catalogued as COSV60973985; called by muse, mutect2, varscan2
- ATP8A2 | c.2789T>A p.I930N | Missense Mutation (SNP) | VAF 99/237 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54955424; called by muse, mutect2, varscan2
- ATR | c.4411T>C p.W1471R | Missense Mutation (SNP) | VAF 60/130 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.923); catalogued as COSV63387155; called by muse, mutect2, varscan2
- CCDC54 | c.515A>C p.K172T | Missense Mutation (SNP) | VAF 82/192 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.814); catalogued as COSV53758818; called by muse, mutect2, varscan2
- CD1B | c.571G>A p.V191I | Missense Mutation (SNP) | VAF 159/362 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs186845827, COSV100939217, COSV63804283; called by muse, mutect2, varscan2
- CHST4 | c.388C>T p.R130W | Missense Mutation (SNP) | VAF 91/219 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368228807; called by muse, mutect2, varscan2
- CNTN3 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 73/154 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs367688857; called by muse, mutect2, varscan2
- COL4A2 | c.2651G>T p.G884V | Missense Mutation (SNP) | VAF 123/287 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV64625009; called by muse, mutect2, varscan2
- DRD5 | c.1004G>T p.C335F | Missense Mutation (SNP) | VAF 129/354 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58577977; called by muse, mutect2, varscan2
- ECEL1 | c.1987C>T p.R663W | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs768312431, COSV58812692; called by muse, mutect2, varscan2
- FILIP1 | c.1151G>A p.R384Q | Missense Mutation (SNP) | VAF 171/422 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.738); catalogued as rs147080592; called by muse, mutect2, varscan2
- FLT1 | c.3733G>A p.D1245N | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as rs372046832, COSV56729596; called by muse, mutect2, varscan2
- FNDC1 | c.1895G>A p.R632H | Missense Mutation (SNP) | VAF 85/161 reads (53%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as rs771786483, COSV51939371, COSV99796761; called by muse, mutect2, varscan2
- HYDIN | c.2484C>A p.N828K | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV100378605; called by mutect2, varscan2
- INSRR | c.3470G>A p.R1157H | Missense Mutation (SNP) | VAF 103/224 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139192917; called by muse, mutect2, varscan2
- KLF3 | c.883G>T p.E295* | Nonsense Mutation (SNP) | VAF 84/218 reads (39%) | catalogued as COSV54711059; called by muse, mutect2, varscan2
- MCOLN3 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 187/415 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV62014488; called by muse, mutect2, varscan2
- MCTP2 | c.1132G>T p.V378F | Missense Mutation (SNP) | VAF 75/165 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV59144890; called by muse, mutect2, varscan2
- MUC17 | c.12334G>A p.A4112T | Missense Mutation (SNP) | VAF 101/332 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs751624526, COSV60290633; called by muse, mutect2, varscan2
- NXF3 | c.338G>C p.W113S | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67703754; called by muse, mutect2, varscan2
- OGA | c.1929T>G p.Y643* | Nonsense Mutation (SNP) | VAF 123/147 reads (84%) | catalogued as COSV63381991; called by muse, mutect2, varscan2
- OR10R2 | c.21C>G p.F7L | Missense Mutation (SNP) | VAF 80/244 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV63768756; called by muse, mutect2, varscan2
- OXSR1 | c.1027T>C p.F343L | Missense Mutation (SNP) | VAF 134/282 reads (48%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV61258959; called by muse, mutect2, varscan2
- PIK3CA | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 108/126 reads (86%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.05); catalogued as COSV55935970; called by muse, mutect2, varscan2
- PPP1R3A | c.610A>T p.K204* | Nonsense Mutation (SNP) | VAF 93/311 reads (30%) | catalogued as COSV52884132; called by muse, mutect2, varscan2
- PSD4 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 92/209 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs201700173, COSV55525638; called by muse, mutect2, varscan2
- QSER1 | c.1876C>G p.L626V (on ENST00000399302; = p.L755V on NM_001076786.3) | Missense Mutation (SNP) | VAF 121/246 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.76); catalogued as COSV67900732; called by muse, mutect2, varscan2
- SCN9A | c.4856G>A p.R1619Q (on ENST00000303354; = p.R1608Q on NM_002977.3) | Missense Mutation (SNP) | VAF 161/372 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs142201175, COSV57612198; called by muse, mutect2, varscan2
- SERPINA1 | c.491C>A p.S164* | Nonsense Mutation (SNP) | VAF 15/166 reads (9%) | catalogued as COSV63345748; called by muse, mutect2, varscan2
- SLC7A2 | c.1909G>A p.A637T (on ENST00000494857 / NM_001370338.1; = p.A676T on NM_003046.6) | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV50255448; called by muse, mutect2, varscan2
- STAG2 | c.462+2T>C p.X154_splice | Splice Site (SNP) | VAF 59/72 reads (82%) | catalogued as COSV54360217; called by muse, mutect2, varscan2
- TENM4 | c.6746G>T p.G2249V | Missense Mutation (SNP) | VAF 30/426 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV53634136, COSV53682930; called by muse, mutect2
- TNFRSF8 | c.616T>A p.S206T | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as COSV55796985; called by muse, mutect2
- TSPAN16 | c.368C>T p.T123I | Missense Mutation (SNP) | VAF 65/166 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs1189304873, COSV57441952, COSV57442423; called by muse, mutect2, varscan2
- UNC13C | c.4468T>A p.L1490M | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52880379; called by mutect2, varscan2
- WDR44 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 226/246 reads (92%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV54160134, COSV54170626; called by muse, mutect2, varscan2
- ZCCHC14 | c.973-2A>C p.X325_splice (on ENST00000268616; = p.X462_splice on NM_015144.3) | Splice Site (SNP) | VAF 57/176 reads (32%) | catalogued as COSV51886741; called by muse, mutect2, varscan2
- ZFYVE26 | c.4599G>A p.W1533* | Nonsense Mutation (SNP) | VAF 32/40 reads (80%) | catalogued as COSV61329272; called by muse, mutect2, varscan2
- ZNF536 | c.170A>G p.E57G | Missense Mutation (SNP) | VAF 78/230 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV62825548; called by muse, mutect2, varscan2
- ZNRF3 | c.733C>T p.R245* (on ENST00000544604 / NM_001206998.2; = p.R145* on NM_032173.3) | Nonsense Mutation (SNP) | VAF 71/90 reads (79%) | catalogued as rs1188411932, COSV60431282; called by muse, mutect2, varscan2
- ZNF26 | c.653A>G p.N218S | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- AC109583.1 | c.147T>G p.T49= | Silent (SNP) | VAF 40/98 reads (41%) | catalogued as COSV59350999; called by muse, mutect2, varscan2
- ALOX15 | c.384G>C p.R128= | Silent (SNP) | VAF 188/494 reads (38%) | catalogued as COSV53398207, COSV53401364; called by muse, mutect2, varscan2
- ANGPT1 | c.1218A>G p.K406= | Silent (SNP) | VAF 79/174 reads (45%) | catalogued as COSV52442389; called by muse, mutect2, varscan2
- ATAD1 | c.333C>T p.I111= | Silent (SNP) | VAF 70/103 reads (68%) | catalogued as COSV57757042; called by muse, mutect2, varscan2
- BRAF | c.1914T>A p.A638= (on ENST00000288602 / NM_001374244.1; = p.A598= on NM_004333.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 84/251 reads (33%) | catalogued as COSV56203004; called by muse, mutect2, varscan2
- CASP8AP2 | c.4191G>A p.P1397= | Silent (SNP) | VAF 98/236 reads (42%) | catalogued as rs766939807, COSV52747447; called by muse, mutect2, varscan2
- CD14 | c.852G>A p.S284= | Silent (SNP) | VAF 56/224 reads (25%) | catalogued as COSV57370840; called by muse, mutect2, varscan2
- CNKSR1 | c.1677G>A p.Q559= (on ENST00000374253 / NM_001297647.2; = p.Q552= on NM_006314.3) | Silent (SNP) | VAF 55/129 reads (43%) | catalogued as COSV58793455; called by muse, mutect2, varscan2
- CSMD1 | c.8637C>T p.G2879= (on ENST00000520002; = p.G2878= on NM_033225.6) | Silent (SNP) | VAF 29/69 reads (42%) | catalogued as rs776260093, COSV100146615, COSV59332793; called by muse, mutect2, varscan2
- DCTN1 | c.2973C>T p.I991= | Silent (SNP) | VAF 90/175 reads (51%) | catalogued as rs140969689, COSV62619536, COSV62619647; called by muse, mutect2, varscan2
- FLT1 | c.1080G>A p.K360= | Silent (SNP) | VAF 126/280 reads (45%) | catalogued as rs755860865, COSV56729610, COSV99146772; called by muse, mutect2, varscan2
- GPNMB | c.1351C>T p.L451= (on ENST00000381990 / NM_001005340.2; = p.L439= on NM_002510.3) | Silent (SNP) | VAF 114/350 reads (33%) | catalogued as rs1226370454, COSV51698928; called by muse, mutect2, varscan2
- GPR4 | c.453G>A p.A151= | Silent (SNP) | VAF 143/362 reads (40%) | catalogued as rs759854339, COSV59917243; called by muse, mutect2, varscan2
- LRRIQ1 | c.1731T>C p.D577= | Silent (SNP) | VAF 36/87 reads (41%) | catalogued as COSV67831826; called by muse, mutect2, varscan2
- MINDY4 | c.1527A>G p.R509= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as COSV54674772; called by muse, mutect2, varscan2
- UEVLD | c.1266T>C p.N422= | Silent (SNP) | VAF 44/100 reads (44%) | catalogued as rs1418415445, COSV57874857; called by muse, mutect2, varscan2
- WWC1 | c.2538G>A p.E846= | Silent (SNP) | VAF 39/108 reads (36%) | catalogued as COSV54651892; called by muse, mutect2, varscan2
- ZSWIM5 | c.873C>T p.H291= | Silent (SNP) | VAF 157/320 reads (49%) | catalogued as COSV62734579; called by muse, mutect2, varscan2
- NDUFB1 | chr14:92121760 G>C | 5'Flank (SNP) | VAF 89/124 reads (72%) | catalogued as rs968978334, COSV54098670; called by muse, mutect2, varscan2
